Surgical pathology report (de-identified scan), TCGA case TCGA-CM-4750, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-4750-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:
Rectosigmoid cancer question . hepatitis.

Specimens Submitted:
1: colon, Sigmoid and upper rectum; resection
2: liver, left; biopsy
3: Proximal margin; excision
4: Distal margin; excision

DIAGNOSIS:

1. COLON, SIGMOID AND UPPER RECTUM; RESECTION:
- INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: RECTOSIGMOID
- TUMOR SIZE: LENGTH IS 3.5 CM, WIDTH IS 3.2 CM, MAXIMAL THICKNESS IS 0.3 CM
- GROSS CONFIGURATION: POLYPOID
- PREEXISTING POLYP (AT THE SITE OF THE CARCINOMA): IDENTIFIED;TUBULOVILLOUS ADENOMA.
- TUMOR INVASION: INVASION INTO SUBMUCOSA.
- SEROUSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: SUSPECTED
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS: FREE OF TUMOR; 4.0 CM BETWEEN DEEPEST TUMOR PORTION AND DEEP (RADIAL SOFT TISSUE) MARGIN.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS (AJCC): pT1
- LYMPH NODES: NUMBER WITH METASTASES: 2; NUMBER EXAMINED: 52
- THE PATHOLOGIC STAGE IS (AJCC): pN1

NOTE: IMMUNOHISTOCHEMICAL STAINS FOR THE TESTED DNA MISMATCH REPAIR PROTEINS (MLH1, PMS2, MSH2, AND MSH6) SHOW THAT EXPRESSION OF ALL PROTEINS IS RETAINED IN THE TUMOR CELLS.

2. LIVER, LEFT; BIOPSY:
- SUBCAPSULAR HEPATIC PARENCHYMA WITH NON-SPECIFIC REACTIVE CHANGES.

NOTE: TRICHROME AND RETICULIN SPECIAL STAINS DO NOT SHOW INCREASED FIBROSIS. AN IRON STAIN SHOWS NO STAINABLE IRON. THERE IS NO EVIDENCE OF AUTOIMMUNE HEPATITIS IN THIS MATERIAL. PART 2 WAS REVIEWED IN CONSULTATION

** Continued on next page **

[page 2 of 4]
WITH [REDACTED]

3. COLON, PROXIMAL MARGIN; EXCISION:
-BENIGN SEGMENT OF COLON.
4. RECTUM, DISTAL MARGIN; EXCISION:
- BENIGN SEGMENT OF RECTUM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:
Result

Special Stain
TRICHROME
IRON
RETIC

Comment

Gross Description:

1. The specimen is received fresh and is labeled "sigmoid and upper rectum, stitch marks proximal". It consists of a rectosigmoid colon that measures 16.5 cm. The serosal surface is smooth. The radial resection margin is inked black and the specimen is opened to reveal a polypoid tumor that is located 5.0 cm from the distal margin. The tumor measures 3.5 cm in length and 3.2 cm in width. Serial sectioning reveals tumor invasion into the muscularis propria to a depth of 0.3 cm, which is 4.0 cm from the closest radial margin. The remaining mucosa shows a 0.3 cm polyp, 1.0 cm from the distal margin. A tattoo site is identified distal to the tumor. The specimen is submitted for lymph node dissection. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM -- proximal margin
DM -- distal margin
RM -- radial margin
T -- tumor
P -- polyp and tattoo site
U -- uninvolved mucosa
LNS -- lymph nodes

2) The specimen is received in formalin, labeled "Left liver biopsy" and consists of two fragments of focally hemorrhagic tan-brown soft tissue

** Continued on next page **

[page 3 of 4]
----- Page 3 of 4
measuring 1.0 x 0.7 x 0.2 and 0.7 x 0.6 x 0.2 cm, which are submitted
entirely.

Summary of sections:
U--undesignated

3) The specimen is received in formalin, labeled "Proximal margin" and consists of a silver metal anastomotic pin measuring 5.8 x 2.8 x 1.5 cm. At the center of the pin, a blue plastic piece is noted. A ring of grossly unremarkable pink tan soft tissue is attached measuring 1.5 x 1.3 x 0.9 cm. Blue suture material is attached. The sutures are removed and the soft tissue is entirely submitted.

Summary of sections:
U--undesignated

4) The specimen is received in formalin, labeled "Distal margin" and consists of a ring of glistening focally hemorrhagic pink tan soft tissue measuring 1.7 x 1.7 x 0.9 cm. Multiple sutures and staples are attached. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U--undesignated

Summary of Sections:

Part 1: colon, Sigmoid and upper rectum; resection

Block	Sect.	Site	PCs
6		BLN	12
1		DM	2
9		LN	27
1		P	1
1		PM	2
1		RM	1
5		T	5
1		U	1

Part 2: liver, left; biopsy

Block	Sect.	Site	PCs
1		u	1

Part 3: Proximal margin; excision

Block	Sect.	Site	PCs
1		u	1

** Continued on next page **

[page 4 of 4]
Part 4: Distal margin; excision

Block	Sect.	Site	PCs
1		u	1

** End of Report **

Source: NCI Genomic Data Commons file 65e3d79c-f6a6-4932-a50a-e0edd3017046 (TCGA-CM-4750.DFA82FCC-99C6-4F13-B3F1-A14615247E2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).